Gene-level copy-number profile of tumor specimen ALCH-B2AL-TTP1-A from ALCHEMIST case ALCH-B2AL, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.1 years (21,945 days).
Specimen ALCH-B2AL-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0a10c128-62a3-4b6b-963a-f11b509daf18.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2AL-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,234 have no estimate.
https://portal.gdc.cancer.gov/files/407b0362-04d7-43e7-91ee-eae7f086f5a8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 70; copy number 1: 3,092; copy number 2: 54,301; copy number 3: 871; copy number 4: 39; copy number 5: 4; copy number 6: 9; copy number 10: 3.

Homozygous deletions (total copy number 0; autosomes only): 70 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,523,648–49,524,185, 2 genes: AC119751.2, AC119751.8.
- chr4:151,027,090–151,027,617, 1 gene: AK4P6.
- chr6:168,053,166–168,101,511, 1 gene: FRMD1.
- chr7:5,274,369–5,425,414, 2 genes (within-gene range 0–6): SLC29A4, TNRC18.
- chr7:140,435,316–140,435,787, 1 gene: AC069335.1.
- chr7:149,285,281–149,297,312, 1 gene (within-gene range 0–2): AC004890.2.
- chr9:125,417,305–125,417,586, 1 gene: Metazoa_SRP.
- chr9:130,892,707–130,896,812, 1 gene: QRFP.
- chr11:67,006,778–67,050,863, 2 genes: SYT12, MIR6860.
- chr12:30,978,308–31,006,010, 1 gene (within-gene range 0–2): AC008013.1.
- chr12:37,575,587–37,576,384, 1 gene: ZNF970P.
- chr15:25,199,448–25,250,940, 29 genes (within-gene range 0–2): SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr15:64,739,891–64,775,589, 2 genes: RBPMS2, MIR1272.
- chr16:75,218,988–75,268,053, 4 genes: CTRB1, AC009078.2, BCAR1, AC009078.3.
- chr16:83,929,796–83,931,223, 1 gene (within-gene range 0–2): AC009119.2.
- chr17:3,577,955–3,578,853, 1 gene (within-gene range 0–1): AC027796.5.
- chr17:16,414,524–16,492,193, 9 genes: AC093484.2, TRPV2, AC093484.1, SNHG29, SNORD49B, SNORD49A, AC093484.4, SNORD65, LRRC75A.
- chr17:30,724,982–30,731,202, 3 genes (within-gene range 0–1): AC127024.7, AC127024.3, AC127024.2.
- chr20:56,667,430–56,667,531, 1 gene: RNU6-1146P.
- chr20:63,974,116–63,980,008, 1 gene (within-gene range 0–1): SAMD10.
- chr22:29,705,256–29,731,833, 3 genes (within-gene range 0–2): AC004882.1, AC004882.2, CABP7.
- chr22:35,335,640–35,336,799, 2 genes (within-gene range 0–2): MIR3909, MIR6069.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 16 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:5,419,827–5,428,927, 4 genes, copy number 5–6 (within-gene range 0–6): AC093620.1, AC092171.1, AC092171.4, AC092171.3.
- chr9:136,779,939–136,800,595, 3 genes, copy number 6 (within-gene range 3–6): ATP6V1G1P3, TMEM141, AL355987.3.
- chr9:136,848,724–136,860,799, 2 genes, copy number 5 (within-gene range 4–5): PHPT1, MAMDC4.
- chr9:136,975,092–136,993,984, 4 genes, copy number 6 (within-gene range 3–6): PTGDS, AL807752.7, LCNL1, PAXX.
- chr21:44,217,014–44,244,993, 3 genes, copy number 10: ICOSLG, AP001059.2, AP001059.1.

Autosomal genes at a single copy (total copy number 1): 3,085. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
